Somatic mutation profile of tumor specimen ALCH-B1VP-TTP1-A (aliquot ALCH-B1VP-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,195 days).
Specimen ALCH-B1VP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f4c80e0-a1ca-4edd-8efd-35c92cf8a4fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VP-NB1-A (Blood Derived Normal), aliquot ALCH-B1VP-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fe983d-1e4f-41a1-ac77-013aedaa796f

The open-access MAF lists 85 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 19, Intron 5, Frame Shift Del 4, In Frame Del 4, Nonsense Mutation 4, 5'UTR 2, RNA 2, 3'Flank 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 214/887 reads (24%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 282/765 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.4440del p.E1481Rfs*10 | Frame Shift Del (DEL) | VAF 24/181 reads (13%) | catalogued as rs1562936717; called by mutect2, pindel, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 48/1244 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- BICC1 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100874752; called by muse, mutect2, varscan2
- BRCA2 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as CM099641; called by muse, mutect2, varscan2
- CSMD3 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 119/856 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52348574; called by muse, mutect2, varscan2
- DDC | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 394/1469 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs758279066; called by muse, mutect2, varscan2
- DMRT1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV66522051; called by muse, mutect2, varscan2
- GJB5 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 130/579 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58355400, COSV58356976; called by muse, mutect2, varscan2
- GRM8 | c.2591C>A p.T864N | Missense Mutation (SNP) | VAF 196/1325 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1375296188; called by muse, mutect2, varscan2
- HBD | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 296/1420 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs34536353, CM023082, CM032939, COSV53082154, COSV99496881; ClinVar: other; called by muse, mutect2, varscan2
- KLHL1 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 52/700 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV64771175; called by muse, mutect2
- MXRA5 | c.8076C>A p.D2692E | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs376516887; called by muse, mutect2, varscan2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 89/461 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- PXDNL | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 290/509 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs558871034, COSV62496125; called by muse, mutect2, varscan2
- RTL1 | c.1803T>A p.S601R | Missense Mutation (SNP) | VAF 89/1234 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV101128459; called by muse, mutect2
- SF3A1 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 113/650 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53167297; called by muse, mutect2, varscan2
- SPTA1 | c.4849C>T p.R1617W | Missense Mutation (SNP) | VAF 374/1485 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs745646823, COSV63756375, COSV63758949; called by muse, mutect2, varscan2
- STAG2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54355722; called by muse, mutect2, varscan2
- STC1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 140/775 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1420271133; called by muse, mutect2, varscan2
- VIRMA | c.214T>C p.F72L | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1217330329; called by muse, mutect2, varscan2
- ZFP57 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190525528; called by muse, mutect2
- ABCA5 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 50/409 reads (12%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4661del p.P1554Lfs*6 | Frame Shift Del (DEL) | VAF 79/360 reads (22%) | called by mutect2, pindel, varscan2
- CDK13 | c.61_63del p.K21del | In Frame Del (DEL) | VAF 46/286 reads (16%) | called by pindel, varscan2
- CNOT4 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 89/597 reads (15%) | called by muse, mutect2, varscan2
- CTRB2 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 401/1284 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- DNAJC30 | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 79/507 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DPEP1 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 131/773 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM71A | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- G2E3 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 86/817 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IGFN1 | c.2132C>T p.P711L (on ENST00000295591 / NM_001367841.1; = p.P3168L on NM_001164586.2) | Missense Mutation (SNP) | VAF 208/821 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMTK3 | c.2365_2379del p.K789_S793del | In Frame Del (DEL) | VAF 71/480 reads (15%) | called by mutect2, pindel, varscan2
- MAG | c.1463G>T p.C488F | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH2B | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- NLRP13 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 111/587 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NMRK2 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- NSD3 | c.799_800del p.K267Vfs*24 | Frame Shift Del (DEL) | VAF 151/336 reads (45%) | called by mutect2, pindel, varscan2
- NXPH2 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR4C13 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PCSK2 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 176/838 reads (21%) | called by muse, mutect2, varscan2
- PLCB1 | c.3571G>T p.G1191* | Nonsense Mutation (SNP) | VAF 87/1279 reads (7%) | called by muse, mutect2
- RNF113A | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SCAF11 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG3 | c.1244dup p.N415Kfs*3 | Frame Shift Ins (INS) | VAF 72/366 reads (20%) | called by pindel, varscan2
- SEMA6B | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHISA7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 91/418 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SRP54 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 69/604 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- STEAP4 | c.35_36del p.T12Nfs*17 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | called by mutect2, pindel*, varscan2*
- TAC3 | c.315_317del p.E106del | In Frame Del (DEL) | VAF 178/929 reads (19%) | called by mutect2, pindel, varscan2
- TMEM222 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 114/557 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WDFY2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- WNK3 | c.2501C>T p.T834I | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H7B | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZNF681 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ATP6V1FNB | c.498C>T p.F166= | Silent (SNP) | VAF 20/438 reads (5%) | catalogued as rs968302900; called by muse, mutect2
- CCDC136 | c.27A>G p.L9= | Silent (SNP) | VAF 96/475 reads (20%) | called by muse, mutect2, varscan2
- CNTN2 | c.2220C>T p.N740= | Silent (SNP) | VAF 68/532 reads (13%) | called by muse, varscan2
- CSMD1 | c.7971G>T p.G2657= (on ENST00000520002; = p.G2656= on NM_033225.6) | Silent (SNP) | VAF 76/448 reads (17%) | catalogued as rs775421314; called by muse, mutect2, varscan2
- CTRB2 | c.42T>C p.G14= | Silent (SNP) | VAF 406/1291 reads (31%) | catalogued as rs941922348; called by muse, mutect2, varscan2
- DEFA6 | c.45C>A p.L15= | Silent (SNP) | VAF 78/377 reads (21%) | called by muse, mutect2, varscan2
- EPN3 | c.516C>T p.Y172= | Silent (SNP) | VAF 37/491 reads (8%) | catalogued as rs776873627; called by muse, mutect2
- GCLM | c.312A>T p.S104= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- HELZ | c.186C>T p.Y62= | Silent (SNP) | VAF 192/627 reads (31%) | catalogued as COSV62381147; called by muse, mutect2, varscan2
- HTRA2 | c.648T>C p.Y216= | Silent (SNP) | VAF 264/1410 reads (19%) | called by muse, mutect2, varscan2
- IL17RD | c.1524T>C p.C508= | Silent (SNP) | VAF 151/559 reads (27%) | called by muse, mutect2, varscan2
- IRS4 | c.3639G>A p.P1213= | Silent (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- KCNH2 | c.1770C>A p.G590= | Silent (SNP) | VAF 208/1353 reads (15%) | called by muse, mutect2, varscan2
- MYO15A | c.1176C>A p.I392= | Silent (SNP) | VAF 404/878 reads (46%) | called by mutect2, varscan2
- NUTM2G | c.810T>C p.F270= | Silent (SNP) | VAF 226/1461 reads (15%) | catalogued as rs1338860062; called by muse, mutect2, varscan2
- PIPOX | c.435C>T p.S145= | Silent (SNP) | VAF 149/919 reads (16%) | catalogued as rs373053963; called by muse, mutect2, varscan2
- POM121L2 | c.1086C>T p.N362= | Silent (SNP) | VAF 121/610 reads (20%) | catalogued as rs1487605445, COSV66276361; called by muse, mutect2, varscan2
- TTC16 | c.648T>C p.F216= | Silent (SNP) | VAF 63/364 reads (17%) | catalogued as COSV58854419; called by mutect2, varscan2
- TYRO3 | c.696C>T p.T232= | Silent (SNP) | VAF 95/514 reads (18%) | catalogued as rs201774612, COSV55485967; called by muse, mutect2, varscan2
- AGAP12P | n.1919G>C | RNA (SNP) | VAF 589/1598 reads (37%) | called by muse, mutect2, varscan2
- CELF3 | c.-783G>T | 5'UTR (SNP) | VAF 90/692 reads (13%) | called by muse, varscan2
- IGHV4-59 | c.-41_-28del | 5'UTR (DEL) | VAF 68/458 reads (15%) | called by mutect2, pindel
- IGSF6 | c.427+23C>T | Intron (SNP) | VAF 135/715 reads (19%) | called by muse, mutect2, varscan2
- NPHP3 | c.2172-35C>A | Intron (SNP) | VAF 59/261 reads (23%) | called by muse, mutect2, varscan2
- PARPBP | c.388-2205C>T | Intron (SNP) | VAF 173/833 reads (21%) | catalogued as rs769732945; called by muse, mutect2, varscan2
- PDZD7 | chr10:101015752 G>A | 3'Flank (SNP) | VAF 232/613 reads (38%) | called by muse, mutect2, varscan2
- PIGF | c.229-30G>A | Intron (SNP) | VAF 72/202 reads (36%) | called by muse, varscan2
- PLCE1 | c.1207-42901_1207-42898dup | Intron (INS) | VAF 89/506 reads (18%) | called by mutect2, pindel, varscan2
- TRBV21OR9-2 | n.89G>A | RNA (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
